Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A03T, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A03T-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:

Palpable left breast cancer showing IDC on core.

Specimens Submitted:

- 1: SP: Sentinel node #1, level one, left axilla (fs)
- 2: SP: Sentinel node #2, level one, left axilla (fs)
- 3: SP: Sentinel node #3, level one, left axilla (fs)
- 4: SP: Left breast
- 5: SP: Level one and two lymph nodes left axilla

DIAGNOSIS:

- 1) LYMPH NODE, SENTINEL #1, LEFT AXILLA LEVEL I, BIOPSY:
- METASTATIC CARCINOMA INVOLVING ONE OUT OF ONE LYMPH NODE (1/1).
- NO EXTRANODAL EXTENSION SEEN.
- 2) LYMPH NODE, SENTINEL #2, LEFT AXILLA LEVEL I, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 3) LYMPH NODE, SENTINEL #3, LEFT AXILLA LEVEL I, BIOPSY:
- METASTATIC CARCINOMA INVOLVING ONE OUT OF ONE LYMPH NODE (1/1).
- NO EXTRANODAL EXTENSION SEEN.
- 4) BREAST, LEFT, TOTAL MASTECTOMY:
- INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE II/III (MODERATE VARIATION IN SIZE AND SHAPE), MEASURING 2.5 CM, GROSSLY.
- DUCTAL CARCINOMA IN SITU (DCIS) IS ALSO IDENTIFIED, SOLID TYPE WITH INTERMEDIATE NUCLEAR GRADE AND MODERATE NECROSIS.
- LOBULAR INVOLVEMENT BY DCIS IS PRESENT.
- THE DCIS CONSTITUTES <= 25% OF THE TOTAL TUMOR MASS, AND IS PRESENT ADMIXED WITH AND AWAY FROM THE INVASIVE COMPONENT.
- THE INVASIVE CARCINOMA IS LOCATED IN THE UPPER OUTER QUADRANT AND CENTRAL AREA.
- THE DCIS IS LOCATED IN THE UPPER OUTER QUADRANT AND CENTRAL AREA.
- NO INVOLVEMENT OF THE NIPPLE BY EITHER IN SITU OR INVASIVE CARCINOMA IS IDENTIFIED.
- VASCULAR INVASION IS PRESENT.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY EITHER INVASIVE OR IN SITU CARCINOMA IS IDENTIFIED.

** Continued on next page **

1C0-0-3

Carcinoma, infiltrating duct, nos 8500/3
Site: breast, nos C50.9
lw
10/21/11

[page 2 of 5]
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES, STROMAL FIBROSIS, ADENOSIS AND FIBROCYSTIC CHANGES.
- RESULTS OF SPECIAL STAINS (ARE AS FOLLOWS:
- Immunohistochemical stains were performed on formalin-fixed tissue with the following results for invasive carcinoma (block 4 T 11):

ESTROGEN RECEPTOR (6F11,
95% nuclear staining with moderate intensity

PROGESTERONE RECEPTOR (1E2;
60% nuclear staining with moderate intensity

HER2 (HercepTest; -
Negative (0)

Controls are satisfactory.

Comment: HercepTestTM) is an FDA-approved method for assessment of HER2 protein overexpression in breast cancer tissue routinely processed for histological evaluation. The HER2 test results are reported in accordance with the ASCO/CAP guideline recommendations for HER2 testing in breast cancer (J Clin Oncol 2007; 25(1):1-28).

- 5) LYMPH NODES, LEFT AXILLA LEVELS I AND II, RESECTION:
- NINE BENIGN LYMPH NODES (0/9).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	NEG-HER2	

Gross Description:

1).The specimen is received fresh for frozen section consultation, labeled "sentinel node number one level 1 left axilla" and consists of a pink-tan lymph node measuring 1.2 x 1.0 x 0.4 cm. Bisected and entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

** Continued on next page **

[page 3 of 5]
2). The specimen is received fresh for frozen section consultation, labeled "sentinel node number two level 1 left axilla" and consists of tan lymph node measuring 1.0 x 0.5 x 0.5 cm. Bisected and entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

3). The specimen is received fresh for frozen section consultation, labeled "sentinel node three level 1 left axilla" and consists of a tan lymph node measuring 1.5 x 0.8 x 0.8 cm. Bisected and entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

4). The specimen is received fresh, labeled "left breast stitch marks axillary tail" and consists of a breast measuring 21.5 x 17.5 x 4 cm with overlying skin ellipse measuring 9.5 x 3 cm. Situated centrally on the skin surface is an everted nipple measuring 1.5 x 1.2 x 0.8 cm and areola measuring 3.4 x 2.5 cm. A suture demarcates the axillary aspect. The posterior surface of the breast is inked black and the specimen is serially sectioned to reveal a centrally located white-tan firm tumor measuring 2.5 x 2.5 x 2 cm with extension into upper outer quadrant, and located 1.1 cm from the deep margin. A metal clip marking the previous biopsy site is identified. Sectioning of the axillary aspect reveals no grossly identifiable lymph nodes. Representative sections are submitted. TPS is taken.

Summary of sections:

N - nipple
NB - nipple base
D - deep margin
BX - biopsy site with tumor
T - tumor
UIQ - upper inner quadrant
LIQ - lower inner quadrant
UOQ - upper outer quadrant
LOQ - lower outer quadrant

5). The specimen is received fresh, labeled "level 1 and 2 lymph nodes left axilla". It consists of a 8 x 8 x 1.5 cm fragment of fibroadipose tissue without orientation. Multiple lymph nodes are identified, ranging in size from 0.3 cm to 1.2 cm. All identified lymph nodes are submitted.

Summary of sections:

LN - whole lymph nodes

** Continued on next page **

[page 4 of 5]
Summary of Sections:

Part 1: SP: Sentinel node #1, level one, left axilla (fs)

Block	Sect.	Site	PCs
1		FSC	1

Part 2: SP: Sentinel node #2, level one, left axilla (fs)

Block	Sect.	Site	PCs
1		FSC	1

Part 3: SP: Sentinel node #3, level one, left axilla (fs)

Block	Sect.	Site	PCs
1		FSC	1

Part 4: SP: Left breast

Block	Sect.	Site	PCs
5		BK	5
1		D	1
2		LIQ	2
2		LOQ	2
2		N	2
1		NB	1
7		T	7
20		TEST	20
2		UIQ	2
2		UOQ	2

Part 5: SP: Level one and two lymph nodes left axilla

Block	Sect.	Site	PCs
4		LN	9

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: METASTATIC DUCT CARCINOMA.
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME
- 3) FROZEN SECTION DIAGNOSIS: METASTATIC DUCT CARCINOMA.
PERMANENT DIAGNOSIS: SAME

** Continued on next page **

[page 5 of 5]
M.D.

** End of Report **

Source: NCI Genomic Data Commons file c3333373-0184-40c0-b50f-6c696a7a0faf (TCGA-AO-A03T.D5EF8C37-811E-42B7-84E5-E6ED71217971.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).